Gene-level copy-number profile of tumor specimen TCGA-W3-AA1V-06B from TCGA case TCGA-W3-AA1V, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 66.4 years (24,260 days).
Specimen TCGA-W3-AA1V-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.b3ba0a44-ad17-4a68-ac9b-40f5b85b6345.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-W3-AA1V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e75a3422-a09d-4167-a218-d4e7b2a0b95e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 3,349; copy number 2: 22,592; copy number 3: 27,900; copy number 4: 3,210; copy number 5: 2,412; copy number 6: 204; copy number 7: 14; copy number 8: 17; copy number 10: 19; copy number 12: 36; copy number 16: 36; copy number 20: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-W3-AA1V-06B-11D-A400-01): tumor purity 0.73, ploidy 2.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:44,527,257–44,718,851, 7 genes (within-gene range 0–2): EIF3J-DT, EIF3J, AC009996.1, SPG11, PATL2, Y_RNA, B2M.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 139 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:106,304,176–106,699,994, 12 genes, copy number 7: RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526.
- chr6:106,738,948–106,739,054, 1 gene, copy number 7: RNU6-117P.
- chr12:57,475,445–58,920,504, 51 genes, copy number 12–16 (within-gene range 2–16): MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3.
- chr12:67,753,701–67,753,817, 1 gene, copy number 7: AC022513.1.
- chr12:69,212,108–72,186,618, 57 genes, copy number 10–20: AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1.
- chr12:91,680,131–92,531,324, 17 genes, copy number 8: AC025254.1, AC090049.2, LINC02404, AC090049.1, LINC01619, AC123512.1, AC025164.2, BTG1, AC025164.1, RPL21P106, Y_RNA, LINC02391, CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1.

Autosomal genes at a single copy (total copy number 1): 970. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
